Gene-level copy-number profile of tumor specimen ALCH-ADNO-TTP1-A from ALCHEMIST case ALCH-ADNO, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 67.7 years (24,737 days).
Specimen ALCH-ADNO-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 37f1d8de-eb83-4973-ba67-113f510a9207.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-ADNO-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,230 have no estimate.
https://portal.gdc.cancer.gov/files/c91cb331-cb7a-4529-a271-4b5392533601

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 70; copy number 1: 5,087; copy number 2: 49,277; copy number 3: 2,996; copy number 4: 600; copy number 5: 136; copy number 6: 107; copy number 7: 44; copy number 8: 67; copy number 9: 7; copy number 12: 2.

Homozygous deletions (total copy number 0; autosomes only): 67 genes in 23 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:10,330,229–10,330,285, 1 gene (within-gene range 0–2): MIR378B.
- chr3:52,794,768–52,835,729, 5 genes (within-gene range 0–2): ITIH3, ITIH4, AC006254.1, ITIH4-AS1, MUSTN1.
- chr3:75,395,188–75,395,536, 2 genes: LSP1P2, AC139453.1.
- chr3:196,211,487–196,243,178, 1 gene (within-gene range 0–2): SLC51A.
- chr4:1,811,479–1,856,156, 1 gene: LETM1.
- chr5:1,005,039–1,006,623, 1 gene: AC116351.2.
- chr5:1,062,896–1,062,974, 1 gene (within-gene range 0–2): MIR4635.
- chr6:10,474,500–10,478,502, 1 gene: LINC02522.
- chr6:10,511,036–10,514,973, 2 genes (within-gene range 0–1): AL139039.3, AL139039.1.
- chr7:1,267,353–1,269,267, 1 gene: AC073094.1.
- chr8:33,715,784–33,723,079, 2 genes (within-gene range 0–1): RN7SL457P, VENTXP5.
- chr8:57,261,226–57,266,613, 1 gene: AC025674.2.
- chr8:140,591,684–140,593,201, 1 gene (within-gene range 0–1): AC067931.2.
- chr8:144,473,412–144,529,132, 10 genes (within-gene range 0–2): FOXH1, PPP1R16A, AC084125.2, GPT, MFSD3, RECQL4, AC084125.4, LRRC14, LRRC24, C8orf82.
- chr9:5,098,341–5,356,525, 15 genes (within-gene range 0–1): MTCO2P11, MTATP6P11, MTCO3P11, MTND4P14, MTND5P14, TCF3P1, IGHEP2, INSL6, AL133547.1, INSL4, RLN2, HMGN2P31, RLN1, AL135786.2, AL135786.1.
- chr9:130,902,438–130,939,286, 1 gene (within-gene range 0–1): FIBCD1.
- chr9:136,830,957–136,831,023, 1 gene (within-gene range 0–2): MIR4292.
- chr10:628,638–631,255, 1 gene (within-gene range 0–1): AL358216.1.
- chr13:110,615,460–110,713,603, 2 genes (within-gene range 0–2): NAXD, CARS2.
- chr15:25,169,337–25,187,616, 11 genes (within-gene range 0–2): DMAC1P1, SNORD115-1, SNORD115-2, SNORD115-3, SNORD115-4, SNORD115-5, SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10.
- chr15:45,129,933–45,167,526, 2 genes (within-gene range 0–2): DUOX1, AC051619.5.
- chr19:10,871,553–10,928,681, 2 genes: CARM1, YIPF2.
- chr19:55,312,029–55,334,048, 2 genes (within-gene range 0–2): AC020922.2, TMEM150B.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 363 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:11,736,084–11,754,802, 1 gene, copy number 5: AGTRAP.
- chr1:19,072,110–19,210,266, 2 genes, copy number 5: AL137127.1, UBR4.
- chr8:102,805,517–103,501,895, 30 genes, copy number 6 (within-gene range 4–6): GASAL1, AZIN1, AP003696.1, MAILR, AP003354.1, RPL5P24, Y_RNA, NPM1P52, AP003550.1, ATP6V1C1, MTND1P5, MTCO1P4, MTCO2P4, LINC01181, BAALC-AS2, BAALC, BAALC-AS1, MIR3151, AC025370.1, FZD6, AC025370.2, CTHRC1, AC012213.3, RNU6-1011P, SLC25A32, AC012213.5, DCAF13, AC012213.2, AC012213.4, AC012213.1.
- chr8:105,929,126–113,436,939, 59 genes, copy number 5–7 (within-gene range 1–7): Y_RNA, SLC16A14P1, AC027031.1, AC027031.2, OXR1, AC090579.1, TAGLN2P1, RNU7-84P, ABRA, AP003789.1, HMGB1P46, ANGPT1, PGAM1P13, AC025508.1, RNA5SP275, RSPO2, NRBF2P4, AURKBP1, EIF3E, AC087620.1, RPS17P14, EMC2, AC022634.1, AC022634.2, TMEM74, TRMT10BP1, AC104248.1, TRHR, NUDCD1, AC021237.1, ENY2, PKHD1L1, MAPK6P5, EBAG9, SYBU, AC079061.1, AC023245.2, AC023245.1, KCNV1, AC027451.1, RPSAP48, AC073023.1, AC090819.1, AC025366.1, AP005357.1, NDUFB9P3, LINC01608, MTCO1P47, LINC01609, AC009930.1, EEF1A1P37, LINC02237, SERPINA15P, H2AZP7, RNU4-37P, CSMD3, AC024996.1, RPL30P16, MIR2053.
- chr8:113,432,224–113,433,129, 1 gene, copy number 5: AC055788.2.
- chr8:117,520,713–125,367,120, 124 genes, copy number 5–9 (broad region; genes not listed).
- chr8:125,648,327–133,134,903, 90 genes, copy number 5–7 (broad region; genes not listed).
- chr8:134,978,827–135,742,495, 6 genes, copy number 5: RPL23AP56, LINC01591, AC040914.1, KHDRBS3, MAPRE1P1, RNU1-35P.
- chr10:7,444,340–8,016,631, 9 genes, copy number 6: LINC02642, RNU6-535P, AL445070.1, ITIH5, ITIH2, KIN, ATP5F1C, TAF3, AL353754.1.
- chr17:72,021,851–72,058,073, 1 gene, copy number 5 (within-gene range 3–5): ROCR.
- chr17:72,033,772–73,911,878, 33 genes, copy number 5 (within-gene range 3–5): AC007461.1, SOX9-AS1, LINC02097, SOX9, LINC00511, LINC02003, AC007639.1, RPL32P33, AC080037.2, SLC39A11, RN7SKP180, AC080037.1, AC011120.1, ATG12P1, POLR3KP2, AC097641.1, SSTR2, COG1, AC097641.2, FAM104A, C17orf80, AC087301.1, CPSF4L, CDC42EP4, SDK2, AC124804.1, AC032019.1, AC032019.2, AC125421.1, LINC00469, LINC02092, AC125421.2, AC137735.1.
- chr21:43,461,960–43,479,534, 2 genes, copy number 12 (within-gene range 12–52): LINC00313, AP001048.1.
- chr22:15,282,557–15,350,043, 5 genes, copy number 5: AP000542.3, AP000542.1, AP000542.2, ZNF72P, BNIP3P2.

Autosomal genes at a single copy (total copy number 1): 5,073. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
